Surgical pathology report (de-identified scan), TCGA case TCGA-D9-A3Z1, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D9-A3Z1-06A (Metastatic).

Department of Cancer Pathology

Patient: XXX

XXX

Age:

Gender:

Examination result

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion): **Melanoma of the skin after excision – not radicalised. Metastases to lymph nodes of the left axilla**

Date of admission

(urgency: Standard)

Material:

1) Material: breast axillary lymph nodes. Method of collection: Total organ resection

Histopathological diagnosis:

Examination performed on:

Metastases melanoma malignum in V/VII lymph nodes of the left axilla.

Macroscopic description:

"Left axillary lymph node"

Surgical specimen sized 14x9x4,5cm, lymph nodes merging in the cross section, partly necrotic.

The largest lymph node sized 7,5x5x4cm.

Microscopic description:

Conglomerate of metastatic lymph nodes melanoma malignum with an extensive necrosis of cancerous tissue reaching out of the the nodal capsule (No V/VII). See also test No.

Assistant:

Pathologist:

Edited by

CONTACT YOUR DOCTOR WITH THIS REPORT!

ICD-O-3

melanoma, Nos

8720/3

Site: lymph node, axillary

C77.3

6-6-12

RO

QIPAA Discrepancy		☒

Source: NCI Genomic Data Commons file e9640e49-a19b-4b23-ab70-fc70b885d60e (TCGA-D9-A3Z1.88D7BFE1-8B3C-451A-A901-9B0C3C9D0A28.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).